Gene-level copy-number profile of tumor specimen ALCH-B3GL-TTP1-A from ALCHEMIST case ALCH-B3GL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Invasive mucinous adenocarcinoma; Age at diagnosis: 65.7 years (24,004 days).
Specimen ALCH-B3GL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a93a652-45ff-4c66-a4eb-638d5592d24a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/be67b0fc-8527-473a-a445-f92e39719196

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 9,596; copy number 2: 41,601; copy number 3: 6,468; copy number 4: 666; copy number 5: 16; copy number 6: 7; copy number 7: 6; copy number 8: 2; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,892,896–12,898,270, 1 gene (within-gene range 0–1): PRAMEF10.
- chr4:4,844,188–4,863,936, 2 genes: LINC01396, MSX1.
- chr7:98,617,285–98,629,869, 1 gene: NPTX2.
- chr9:130,400,266–130,400,565, 1 gene (within-gene range 0–1): RN7SL665P.
- chr9:136,647,872–136,660,421, 1 gene (within-gene range 0–4): AL590226.1.
- chr9:136,759,634–136,766,255, 1 gene: LCN15.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–5): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–3): CCDC183-AS1.
- chr12:34,162,477–34,166,954, 2 genes: AC140847.3, TUBB8P4.
- chr13:19,182,038–19,227,432, 2 genes: AL139327.1, PSPC1P1.
- chr16:58,665,109–58,706,297, 2 genes: SLC38A7, AC012183.1.
- chr17:9,171,068–9,179,118, 1 gene (within-gene range 0–1): AC005695.1.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,604,269–234,647,571, 4 genes, copy number 6 (within-gene range 4–6): IRF2BP2, AL160408.2, LINC00184, AL160408.5.
- chr5:14,143,342–14,532,128, 2 genes, copy number 5: TRIO, AC016549.1.
- chr7:20,217,577–20,221,700, 1 gene, copy number 5: AC005083.1.
- chr9:12,134–89,850, 7 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:112,713–118,204, 2 genes, copy number 8: LINC01388, FOXD4.
- chr9:136,673,143–136,724,742, 2 genes, copy number 5–6 (within-gene range 2–6): AGPAT2, DIPK1B.
- chr9:136,754,386–136,758,543, 1 gene, copy number 5: LCN8.
- chr9:136,779,939–136,800,595, 3 genes, copy number 5 (within-gene range 0–5): ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 7 (within-gene range 3–7): AJM1, PHPT1, MAMDC4.
- chr9:136,969,243–136,971,990, 1 gene, copy number 5: LINC02692.
- chr11:65,354,751–65,357,613, 1 gene, copy number 7: TIGD3.
- chr19:999,796–1,002,757, 1 gene, copy number 14 (within-gene range 4–14): AC004528.1.
- chr19:1,103,926–1,106,791, 1 gene, copy number 7: GPX4.
- chr20:64,105,820–64,107,171, 1 gene, copy number 7: NPBWR2.
- chr21:33,324,429–33,359,864, 2 genes, copy number 6: IFNAR1, USF1P1.

Autosomal genes at a single copy (total copy number 1): 9,573. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
